Somatic mutation profile of tumor specimen TCGA-AA-3950-01A (aliquot TCGA-AA-3950-01A-02W-0995-10) from TCGA case TCGA-AA-3950, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.8 years (29,130 days).
Specimen TCGA-AA-3950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8ebe550-b102-4da5-8dcf-4bfb9850d60c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3950-10A (Blood Derived Normal), aliquot TCGA-AA-3950-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3803523-25d1-41c0-9cee-f159d1ccafb0

The open-access MAF lists 1,331 somatic variants for this specimen: 1,004 protein-altering or splice-affecting, 311 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 686, Silent 311, Frame Shift Del 181, Nonsense Mutation 56, Frame Shift Ins 28, Splice Site 24, In Frame Del 13, Splice Region 12, Intron 6, RNA 6, Nonstop Mutation 3, 3'UTR 2.

Variants (750 of 1,331; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 44/182 reads (24%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- APC | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 34/194 reads (18%) | catalogued as rs137854573, CM920034, COSV57321615; ClinVar: pathogenic; called by muse, varscan2
- BRIP1 | c.3440dup p.N1147Kfs*2 | Frame Shift Ins (INS) | VAF 36/210 reads (17%) | catalogued as rs753683450; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- COL3A1 | c.1471C>T p.R491* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as rs1057518075, CM157982, COSV58585171, COSV58589931; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- KCNQ2 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as rs118192214, CM033390; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2850+1G>A p.X950_splice | Splice Site (SNP) | VAF 8/48 reads (17%) | catalogued as rs1131691122, CS031788, CS086413, COSV62196412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RNF43 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | hotspot (GDC flag); catalogued as rs786205215, CM154177, COSV68457376; ClinVar: pathogenic; called by muse, mutect2
- TAT | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 132/620 reads (21%) | catalogued as rs118203914, CM920661, COSV63532532; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.1257del p.R420Gfs*20 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs118203506, CD991903; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- AAK1 | c.1460G>A p.G487D | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.093); catalogued as COSV101117253; called by muse, mutect2, varscan2
- ABCA13 | c.11313G>A p.W3771* | Nonsense Mutation (SNP) | VAF 189/1296 reads (15%) | catalogued as COSV71292682; called by muse, mutect2, varscan2
- ACHE | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399916623, COSV53816542; called by muse, mutect2, varscan2
- ACP2 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs752483023; called by muse, mutect2, varscan2
- ACSBG1 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1421589381, COSV51908702; called by muse, mutect2
- ACSM2A | c.382C>T p.R128* (on ENST00000219054; = p.R49* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 41/294 reads (14%) | catalogued as rs748565082, COSV54589440; called by muse, mutect2, varscan2
- ACTN2 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV63978276; called by muse, mutect2
- ADAM2 | c.2145dup p.W716Mfs*4 | Frame Shift Ins (INS) | VAF 17/97 reads (18%) | catalogued as rs764499662; called by mutect2, pindel, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 56/338 reads (17%) | catalogued as rs546931496; called by mutect2, varscan2
- ADAMTS9 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 38/748 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs373729997; called by muse, mutect2
- ADCK1 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs112630340, COSV53078037; called by mutect2, varscan2
- ADCY2 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.042); catalogued as COSV57866859; called by muse, varscan2
- ADD2 | c.817A>G p.N273D | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100035150; called by muse, mutect2, varscan2
- ADGRF3 | c.3101G>A p.R1034H (on ENST00000311519 / NM_001145168.1; = p.R835H on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs752261145, COSV100274892; called by mutect2, varscan2
- ADGRG4 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755135197, COSV54950521, COSV54963624; called by muse, mutect2, varscan2
- AGAP3 | c.2405C>T p.T802M (on ENST00000622464; = p.T838M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs746755216; called by muse, mutect2, varscan2
- AGPAT1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1193939291; called by muse, mutect2, varscan2
- AGPS | c.969_971del p.K323del | In Frame Del (DEL) | VAF 24/128 reads (19%) | catalogued as rs1390890779; called by pindel, varscan2
- AKAP11 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746925599, COSV50299304; called by muse, mutect2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | catalogued as rs758955164; called by mutect2, pindel, varscan2
- ALMS1 | c.8162G>A p.R2721Q | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.181); catalogued as rs745857579, COSV52507270; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs1341338515; called by mutect2, varscan2
- ALPK3 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as rs142807181; called by muse, mutect2, varscan2
- ANK3 | c.4030C>T p.Q1344* (on ENST00000280772 / NM_001320874.2; = p.Q478* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 4/62 reads (6%) | catalogued as COSV55049539; called by muse, mutect2
- ANK3 | c.3361C>T p.R1121C (on ENST00000280772 / NM_001320874.2; = p.R255C on NM_001149.3) | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759013111, COSV55064344; called by muse, mutect2, varscan2
- ANKRD11 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56365935; called by muse, varscan2
- ANO1 | c.2654C>T p.A885V | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.42); catalogued as COSV100797035; called by muse, varscan2
- ANO4 | c.1392G>T p.E464D (on ENST00000392977 / NM_001286615.2; = p.E429D on NM_178826.4) | Missense Mutation (SNP) | VAF 223/955 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs766389994; called by muse, mutect2, varscan2
- APAF1 | c.3673G>A p.V1225M (on ENST00000551964 / NM_181861.2; = p.V1171M on NM_001160.3) | Missense Mutation (SNP) | VAF 114/361 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs201029707; called by muse, mutect2, varscan2
- APOB | c.6137T>C p.V2046A | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99264670; called by muse, mutect2, varscan2
- AR | c.1597G>A p.G533R | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (1); catalogued as COSV65961312; called by muse, mutect2, varscan2
- ARHGAP21 | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs764390405; called by mutect2, varscan2
- ARHGAP24 | c.2179del p.S727Pfs*6 (on ENST00000395184 / NM_001025616.3; = p.S634Pfs*6 on NM_031305.3) | Frame Shift Del (DEL) | VAF 18/155 reads (12%) | catalogued as rs753807502; called by mutect2, pindel, varscan2
- ARHGEF10 | c.2470C>T p.R824* (on ENST00000398564; = p.R799* on NM_014629.4) | Nonsense Mutation (SNP) | VAF 74/369 reads (20%) | catalogued as rs1297695311, COSV50653121; called by muse, mutect2, varscan2
- ARHGEF11 | c.1648+1G>T p.X550_splice | Splice Site (SNP) | VAF 143/916 reads (16%) | catalogued as COSV100809894; called by muse, mutect2, varscan2
- ARID1A | c.6055C>A p.H2019N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100250889; called by muse, mutect2, varscan2
- ARMCX1 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs1331990269; called by muse, mutect2
- ASB14 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762743268, COSV55699478; called by muse, mutect2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 133/802 reads (17%) | catalogued as rs749460467; called by mutect2, pindel, varscan2
- ASCC2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs754012177, COSV57077096; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs747570359; called by mutect2, varscan2
- ASTN2 | c.1268G>A p.R423H (on ENST00000313400 / NM_001365069.1; = p.R372H on NM_014010.5) | Missense Mutation (SNP) | VAF 31/526 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as rs149596951; called by muse, mutect2
- ATG2A | c.5782G>A p.A1928T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs1294226231; called by muse, mutect2, varscan2
- ATP5F1B | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 14/189 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs1198897487; called by muse, mutect2
- ATP6V1B1 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52269873; called by muse, mutect2, varscan2
- ATP8B2 | c.391A>G p.T131A (on ENST00000672630; = p.T98A on NM_001005855.2) | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.591); catalogued as COSV100527829; called by muse, mutect2, varscan2
- ATP9A | c.1827G>C p.E609D | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as COSV58765094; called by muse, mutect2, varscan2
- AUTS2 | c.3178C>T p.R1060C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61390104; called by muse, mutect2, varscan2
- AXDND1 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779560311, COSV100858293; called by muse, mutect2, varscan2
- BACH1 | c.442T>C p.S148P | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs111499444; called by muse, mutect2, varscan2
- BCL9 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs200915171, COSV52349710; called by muse, varscan2
- BCL9 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as rs782492964, COSV52347906; called by muse, varscan2
- BIRC6 | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.799); catalogued as rs775469848, COSV101428041; called by muse, mutect2, varscan2
- BLM | c.2268del p.D757Tfs*4 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | catalogued as rs747341586; called by mutect2, pindel, varscan2
- BMP5 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 76/516 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs368735753; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BPHL | c.381G>A p.A127= | Splice Region (SNP) | VAF 81/612 reads (13%) | catalogued as rs150230595; called by muse, mutect2, varscan2
- BPIFA1 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as COSV62824277; called by muse, mutect2, varscan2
- BRWD3 | c.4694G>A p.R1565K | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV64744064; called by muse, mutect2, varscan2
- C12orf50 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 60/441 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs1268285762; called by muse, mutect2, varscan2
- C1GALT1 | c.881C>A p.P294H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV56179548; called by mutect2, varscan2
- C1orf52 | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV99640956; called by muse, mutect2
- C3 | c.3133del p.A1045Pfs*26 | Frame Shift Del (DEL) | VAF 8/85 reads (9%) | catalogued as COSV99837440; called by mutect2, pindel, varscan2
- CA12 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1329647552; called by muse, mutect2, varscan2
- CACHD1 | c.3511G>A p.V1171I | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as COSV99261822, COSV99262929; called by muse, mutect2, varscan2
- CACNA1E | c.3898A>G p.M1300V | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1033599027, COSV100701660; called by muse, mutect2
- CACNA1F | c.2597C>T p.T866I | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV100544333; called by muse, mutect2, varscan2
- CACNA1F | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV59904356; called by muse, mutect2, varscan2
- CAMK1 | c.583T>C p.Y195H | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV56540171; called by muse, mutect2, varscan2
- CAMSAP1 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | catalogued as rs1451120273; called by muse, mutect2
- CASP7 | c.375del p.A126Lfs*17 | Frame Shift Del (DEL) | VAF 20/192 reads (10%) | catalogued as rs1247046723, COSV61881818; called by mutect2, pindel
- CAVIN1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1457408109; called by mutect2, varscan2
- CCDC158 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs759340288, COSV66355718; called by muse, mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC88A | c.2032del p.T678Hfs*8 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as COSV55059487; called by mutect2, varscan2
- CCDC9B | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs575116596; called by mutect2, varscan2
- CCK | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs370480453; called by muse, mutect2, varscan2
- CCT4 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101075122; called by muse, mutect2
- CD163L1 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs371920759; called by muse, mutect2, varscan2
- CD1E | c.419T>C p.M140T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100936948; called by mutect2, varscan2
- CD300LB | c.283A>G p.R95G | Missense Mutation (SNP) | VAF 115/601 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58726244; called by muse, mutect2, varscan2
- CDC42BPA | c.3901C>T p.R1301* (on ENST00000334218 / NM_001366019.2; = p.R1288* on NM_003607.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as rs760385271, COSV100504301; called by muse, mutect2, varscan2
- CDH22 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748074243, COSV100953012; called by muse, mutect2, varscan2
- CDH6 | c.2023G>A p.G675S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.722); catalogued as rs1230322802, COSV54070807; called by muse, mutect2, varscan2
- CDH9 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs372629879; called by muse, mutect2, varscan2
- CDK16 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99331771; called by muse, mutect2, varscan2
- CDR2L | c.138G>T p.E46D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771785431; called by muse, mutect2, varscan2
- CDRT1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs758747777; called by muse, varscan2
- CEACAM4 | c.626C>A p.S209* | Nonsense Mutation (SNP) | VAF 24/122 reads (20%) | catalogued as rs570247564, COSV55732033; called by muse, mutect2, varscan2
- CENPF | c.5854_5856del p.E1952del | In Frame Del (DEL) | VAF 7/55 reads (13%) | catalogued as rs764301431; called by pindel, varscan2
- CFAP57 | c.1846G>T p.G616* | Nonsense Mutation (SNP) | VAF 55/307 reads (18%) | catalogued as COSV100993882; called by muse, mutect2, varscan2
- CGN | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as rs1013068853, COSV99642103; called by muse, mutect2, varscan2
- CKAP5 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.843); catalogued as rs1388942112; called by muse, mutect2, varscan2
- CLEC16A | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68497894; called by muse, mutect2, varscan2
- CLEC4F | c.1755G>A p.W585* | Nonsense Mutation (SNP) | VAF 11/184 reads (6%) | catalogued as COSV99713646; called by muse, mutect2
- CLIP1 | c.4247G>A p.R1416H (on ENST00000620786 / NM_001247997.1; = p.R1405H on NM_002956.2) | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1275907046, COSV56801414; called by muse, mutect2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | catalogued as rs369752219; called by mutect2, varscan2
- CNTNAP2 | c.3799G>A p.V1267I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as rs778901819, COSV62149554, COSV62170228; called by muse, mutect2, varscan2
- CNTRL | c.5405del p.K1802Sfs*9 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | catalogued as rs1217756472; called by mutect2, pindel, varscan2
- COL12A1 | c.8322G>C p.G2774= | Splice Region (SNP) | VAF 7/89 reads (8%) | catalogued as COSV59394073; called by muse, mutect2
- COL12A1 | c.170T>C p.I57T | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs1336472494; called by muse, mutect2, varscan2
- COL22A1 | c.1707del p.Q571Kfs*85 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | catalogued as COSV100278516; called by mutect2, pindel, varscan2
- COL4A4 | c.1884del p.P630Qfs*23 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as COSV100306098; called by mutect2, pindel, varscan2
- COPA | c.2240G>T p.R747L | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV54102228, COSV99615067; called by muse, mutect2, varscan2
- COPA | c.1078G>T p.G360C | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV99615072; called by muse, mutect2, varscan2
- COPB1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 79/365 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs148278102; called by muse, mutect2, varscan2
- CPB2 | c.340del p.R114Efs*13 | Frame Shift Del (DEL) | VAF 82/521 reads (16%) | catalogued as COSV51672196; called by mutect2, pindel, varscan2
- CPLANE1 | c.9142C>T p.P3048S | Missense Mutation (SNP) | VAF 72/445 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV57059261; called by muse, mutect2, varscan2
- CPSF2 | c.1963G>C p.D655H | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV54097819; called by muse, mutect2
- CR1 | c.4530G>T p.K1510N | Missense Mutation (SNP) | VAF 86/418 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV100887482; called by muse, mutect2, varscan2
- CRABP2 | c.252C>T p.S84= | Splice Region (SNP) | VAF 9/88 reads (10%) | catalogued as rs758929456, COSV100957544; called by mutect2, varscan2
- CRP | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.68); catalogued as rs200949626, COSV54814574; called by muse, mutect2, varscan2
- CSMD1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.842); catalogued as rs528712229, COSV101212095; called by muse, mutect2, varscan2
- CTSE | c.949G>C p.V317L (on ENST00000360218; = p.V312L on NM_001910.4) | Missense Mutation (SNP) | VAF 76/427 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100733565; called by muse, mutect2, varscan2
- CYP11B1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV52824341; called by muse, mutect2, varscan2
- DAB2IP | c.1571G>A p.R524H (on ENST00000408936; = p.R496H on NM_032552.3) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs146233036; called by muse, mutect2, varscan2
- DCHS1 | c.9572G>A p.R3191Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as rs759274363; called by muse, mutect2, varscan2
- DDI1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1386949019, COSV56385343; called by muse, mutect2
- DDR1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as rs750525973, COSV61326948; called by muse, mutect2, varscan2
- DDX43 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs944028999, COSV64836379; called by muse, mutect2, varscan2
- DDX60 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs747328711, COSV67098921; called by muse, mutect2, varscan2
- DGKA | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1026981531; called by muse, mutect2, varscan2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 50/224 reads (22%) | catalogued as rs756920263; called by mutect2, varscan2
- DIP2C | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs1486172663, COSV55172523; called by muse, mutect2, varscan2
- DNAH3 | c.11579T>C p.V3860A | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.672); catalogued as rs1329422203; called by mutect2, varscan2
- DNAH5 | c.6487C>T p.R2163W | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757370062, COSV99447916; called by muse, mutect2, varscan2
- DNAJC11 | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99602004; called by muse, mutect2, varscan2
- DNMT3B | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs777301633; called by mutect2, varscan2
- DOK5 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.932); catalogued as COSV52817022; called by muse, mutect2, varscan2
- DOP1A | c.4735C>T p.Q1579* | Nonsense Mutation (SNP) | VAF 26/82 reads (32%) | catalogued as rs1212567628; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 26/138 reads (19%) | catalogued as rs35482889; called by mutect2, varscan2
- DPYSL5 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1558337060, COSV99982077; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DRAM2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99713351; called by muse, mutect2, varscan2
- DSCAML1 | c.3764C>T p.A1255V (on ENST00000321322; = p.A1195V on NM_020693.4) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV58380558; called by muse, mutect2
- DSEL | c.3078dup p.Q1027Sfs*28 | Frame Shift Ins (INS) | VAF 14/88 reads (16%) | catalogued as rs762694026; called by mutect2, varscan2
- DSG1 | c.2765T>C p.V922A | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99936005; called by muse, mutect2, varscan2
- DSG4 | c.425A>C p.E142A | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.826); catalogued as COSV57397435; called by muse, mutect2, varscan2
- DTNB | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV56478667, COSV99976996; called by muse, mutect2, varscan2
- DTNBP1 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 30/167 reads (18%) | catalogued as rs367702294; called by muse, mutect2, varscan2
- DYNC2I1 | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV68106773; called by muse, mutect2, varscan2
- DYNC2LI1 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 41/324 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99571030; called by muse, mutect2, varscan2
- DZIP1 | c.2328del p.E777Kfs*6 (on ENST00000347108; = p.E758Kfs*6 on NM_014934.5) | Frame Shift Del (DEL) | VAF 76/655 reads (12%) | catalogued as rs1234396729; called by mutect2, pindel, varscan2
- EARS2 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs376807600; called by muse, mutect2, varscan2
- EBF3 | c.1435C>T p.Q479* (on ENST00000355311 / NM_001375392.1; = p.Q470* on NM_001005463.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/126 reads (20%) | catalogued as COSV100799349, COSV62480854; called by muse, mutect2, varscan2
- EBNA1BP2 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99355882; called by muse, mutect2, varscan2
- EDN2 | c.421G>T p.G141* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV101006327; called by muse, mutect2, varscan2
- EFCAB13 | c.1024del p.S342Afs*25 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | catalogued as rs759569556; called by mutect2, pindel, varscan2
- ELOA2 | c.1859G>C p.R620T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.595); catalogued as COSV55297755; called by muse, mutect2, varscan2
- EML4 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 96/460 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs573955552, COSV100580774; called by mutect2, varscan2
- ENDOD1 | c.1385C>T p.T462I | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1338399663; called by muse, mutect2
- EPC1 | c.13T>C p.S5P | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53925932; called by muse, mutect2
- EPHA3 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1373094456, COSV60697307; called by muse, mutect2, varscan2
- EPHA3 | c.2538del p.M847Wfs*10 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as rs1317589623; called by pindel, varscan2
- ERBB3 | c.3793C>T p.R1265W | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs369300309; called by muse, mutect2, varscan2
- ERBIN | c.3922del p.H1308Ifs*17 (on ENST00000284037 / NM_001253697.2; = p.H1267Ifs*17 on NM_018695.4) | Frame Shift Del (DEL) | VAF 6/55 reads (11%) | catalogued as COSV52316665; called by mutect2, pindel
- ERGIC3 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs199935905; called by muse, mutect2, varscan2
- ERP44 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 96/685 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52431460; called by muse, mutect2, varscan2
- EYA4 | c.579C>T p.Y193= | Splice Region (SNP) | VAF 6/48 reads (13%) | catalogued as rs747954279, COSV62052786; called by muse, varscan2
- F2R | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375693604, COSV100058491; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM120A | c.1360C>A p.P454T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV52902279; called by muse, mutect2, varscan2
- FAM214B | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 3/13 reads (23%) | catalogued as rs1337531430; called by muse, mutect2
- FAM219A | c.382G>A p.G128S (on ENST00000445726; = p.G111S on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs759172112; called by mutect2, varscan2
- FAM229B | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs149743977; called by muse, mutect2, varscan2
- FANK1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 151/964 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as COSV100904814; called by muse, mutect2, varscan2
- FCGBP | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1482601765; called by muse, mutect2, varscan2
- FHL1 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1379221574, COSV61780207; called by muse, mutect2, varscan2
- FLNB | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs773392236; called by muse, mutect2, varscan2
- FLVCR2 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs772508772, COSV53163538; called by mutect2, varscan2
- FN1 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 53/354 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs761729774, COSV60550427; called by muse, mutect2, varscan2
- FUBP3 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as rs760166472, COSV60513868; called by muse, mutect2, varscan2
- GABPA | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61396174; called by muse, mutect2, varscan2
- GALNTL5 | c.153del p.V52Cfs*17 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs746301883; called by mutect2, pindel, varscan2
- GASK1B | c.1268G>T p.R423M | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56707303; called by muse, mutect2, varscan2
- GLIPR1 | c.428G>A p.W143* | Nonsense Mutation (SNP) | VAF 190/663 reads (29%) | catalogued as rs770029786; called by muse, mutect2, varscan2
- GPLD1 | c.2463_2465del p.R821del | In Frame Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs778753458; called by mutect2, pindel, varscan2
- GPM6A | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 58/405 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54554724, COSV99704832; called by muse, mutect2, varscan2
- GRAMD1A | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1411852504; called by muse, mutect2, varscan2
- GRIK2 | c.1453G>T p.D485Y | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293530685; called by muse, mutect2, varscan2
- GZMA | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99956636; called by muse, mutect2, varscan2
- HAL | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.221); catalogued as rs758667702; called by muse, mutect2, varscan2
- HERC1 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs527469204; called by muse, mutect2, varscan2
- HIF1A | c.359T>C p.M120T | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1320657337; called by muse, mutect2, varscan2
- HLA-B | c.626dup p.T211Dfs*10 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | catalogued as rs748204482, COSV69520417; called by pindel, varscan2
- HLA-DPA1 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as rs1198838561, COSV69823489; called by muse, mutect2, varscan2
- HMGCR | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 298/2030 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1045190482; called by muse, mutect2, varscan2
- HMGCS2 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775277893, COSV101024738; called by muse, mutect2, varscan2
- HOXD11 | c.790del p.Q264Sfs*28 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as rs778212888; called by mutect2, pindel, varscan2
- HSPA2 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as rs1251874092; called by muse, varscan2
- HTR5A | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs774800359, COSV55281201; called by muse, mutect2, varscan2
- HUWE1 | c.12619G>A p.V4207I | Missense Mutation (SNP) | VAF 45/550 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.92); catalogued as COSV53357466; called by muse, mutect2
- HYDIN | c.11699C>T p.P3900L | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as rs370482819; called by muse, mutect2, varscan2
- IFI16 | c.1829T>C p.V610A (on ENST00000295809 / NM_001364867.2; = p.V554A on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99857282; called by muse, mutect2
- IFT140 | c.2786C>T p.T929M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757585192, COSV54152237; called by muse, mutect2, varscan2
- IFT172 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 26/226 reads (12%) | catalogued as rs1213400658, COSV99562052; called by muse, mutect2, varscan2
- IGSF10 | c.4656G>A p.M1552I | Missense Mutation (SNP) | VAF 142/681 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV99176780; called by muse, mutect2, varscan2
- IKZF3 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 48/563 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53108228; called by muse, mutect2
- IL13RA1 | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.895); catalogued as COSV100861712; called by muse, mutect2, varscan2
- IMMT | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 147/611 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV99607133; called by muse, mutect2, varscan2
- IMPG1 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV64062069; called by muse, mutect2
- INO80D | c.1540del p.M514Wfs*5 | Frame Shift Del (DEL) | VAF 27/116 reads (23%) | catalogued as COSV68960008; called by mutect2, varscan2
- INSRR | c.2463G>T p.K821N | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV100947298; called by muse, mutect2, varscan2
- IQCE | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as rs780175292, COSV58078120; called by muse, mutect2
- IQCJ-SCHIP1 | c.1669G>A p.A557T (on ENST00000485419 / NM_001197113.1; = p.A481T on NM_014575.3) | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.766); catalogued as rs757171954, COSV100541885; called by muse, mutect2, varscan2
- IQGAP3 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV100752102; called by muse, mutect2, varscan2
- IRAG1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs373371120, COSV101351693; called by muse, mutect2
- ITGAD | c.1474T>C p.S492P | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs780476230; called by muse, mutect2, varscan2
- ITGAM | c.1441del p.H481Ifs*45 (on ENST00000648685 / NM_001145808.2; = p.H481Ifs*44 on NM_000632.4) | Frame Shift Del (DEL) | VAF 24/252 reads (10%) | catalogued as rs1303173835; called by mutect2, pindel
- ITGB8 | c.1820G>A p.C607Y | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771587942, COSV56016394; called by muse, mutect2, varscan2
- ITPR2 | c.7771C>T p.H2591Y | Missense Mutation (SNP) | VAF 33/597 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs1446180180; called by muse, mutect2
- ITSN1 | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs913872456, COSV101180455; called by muse, mutect2
- JCAD | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs376141365; called by mutect2, varscan2
- KANK2 | c.1625C>T p.A542V (on ENST00000586659 / NM_001379562.1; = p.A550V on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV62009071; called by muse, mutect2, varscan2
- KCNA1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs746862982, COSV66836864; called by mutect2, varscan2
- KCNB1 | c.1336G>A p.V446I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs776968332, COSV65569893; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCND3 | c.1898del p.P633Lfs*13 | Frame Shift Del (DEL) | VAF 45/296 reads (15%) | catalogued as COSV56188292; called by mutect2, pindel, varscan2
- KDELR2 | c.584_586del p.F195del | In Frame Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs766087250; called by pindel, varscan2
- KLHL7 | c.478G>A p.E160K (on ENST00000339077 / NM_001031710.3; = p.E112K on NM_018846.5) | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV59162913; called by muse, mutect2
- KLKB1 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146525902; called by muse, mutect2, varscan2
- KRTAP4-12 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs768655983; called by muse, mutect2
- L1TD1 | c.1346A>G p.H449R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100776551; called by muse, mutect2
- LCE5A | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100524208, COSV57501061; called by muse, varscan2
- LHPP | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs538187592; called by muse, mutect2, varscan2
- LIMA1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 58/967 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs146061384; called by muse, mutect2
- LLCFC1 | c.409C>T p.P137S (on ENST00000458732; = p.P106S on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV100787091; called by muse, mutect2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 36/226 reads (16%) | catalogued as rs748712732; called by mutect2, varscan2
- LOXL2 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755780161, COSV66691556; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC61 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs923969650, COSV56231794; called by muse, mutect2, varscan2
- LYST | c.2915T>C p.M972T | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.276); catalogued as rs755912639, COSV101088791; called by muse, mutect2, varscan2
- MACC1 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV100255719; called by muse, mutect2
- MADD | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs752184946; called by muse, mutect2, varscan2
- MAP2 | c.4577A>G p.K1526R | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99558434; called by muse, mutect2, varscan2
- MAP2K3 | c.124del p.R42Gfs*24 (on ENST00000342679 / NM_145109.3; = p.R13Gfs*24 on NM_002756.4) | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs1567665648, COSV57561353; called by mutect2, pindel, varscan2
- MAP2K3 | c.119C>A p.P40H (on ENST00000342679 / NM_145109.3; = p.P11H on NM_002756.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs775653621; called by mutect2, varscan2
- MAPK3 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs754076411; called by muse, mutect2, varscan2
- MASP1 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs142112097; called by muse, mutect2, varscan2
- MBNL1 | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs753484865; called by muse, mutect2, varscan2
- MCC | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs757539653, COSV56735147; called by muse, mutect2, varscan2
- MCOLN2 | c.382T>C p.Y128H | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV99393714; called by muse, mutect2, varscan2
- MDGA2 | c.2222G>A p.R741Q (on ENST00000399232 / NM_001113498.2; = p.R443Q on NM_182830.4) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); catalogued as rs750500943, COSV62098965; called by muse, mutect2, varscan2
- MDN1 | c.12325_12327del p.K4109del | In Frame Del (DEL) | VAF 31/233 reads (13%) | catalogued as rs1358458245; called by mutect2, pindel, varscan2
- MED14 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 67/324 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as rs754791620; called by muse, mutect2, varscan2
- MED23 | c.1634C>T p.T545I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100644759; called by muse, mutect2, varscan2
- MELK | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as rs757367254, COSV53197993; called by muse, mutect2, varscan2
- METTL6 | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1283698678; called by muse, mutect2
- MFSD13A | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775779303; called by muse, mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | catalogued as rs769987847; called by pindel, varscan2
- MMP16 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 11/229 reads (5%) | catalogued as COSV54175541, COSV99689503; called by muse, mutect2
- MPDZ | c.4492A>G p.S1498G | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1191820589; called by muse, mutect2, varscan2
- MPP5 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs778846917, COSV55529238; called by muse, mutect2, varscan2
- MRPL13 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 76/550 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV60367824; called by muse, mutect2, varscan2
- MRPS30 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs534375825, COSV50181666; called by muse, mutect2, varscan2
- MRPS31 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs757451497, COSV60267041; called by muse, varscan2
- MTRR | c.1235del p.L412Cfs*157 (on ENST00000264668; = p.L385Cfs*157 on NM_002454.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 34/230 reads (15%) | catalogued as COSV52945148; called by mutect2, pindel, varscan2
- MUC17 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs567129894, COSV60283667; called by muse, mutect2, varscan2
- MUC4 | c.15463C>T p.R5155C (on ENST00000463781 / NM_018406.7; = p.R919C on NM_004532.6) | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs751791718, COSV100206269; called by muse, mutect2, varscan2
- MYH10 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52611796; called by muse, mutect2, varscan2
- MYO18B | c.5318A>G p.H1773R | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.192); catalogued as rs771051217; called by muse, mutect2
- MYO9B | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs908069730; called by muse, mutect2
- MYOM1 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 61/309 reads (20%) | catalogued as rs1447131267, COSV55286036; called by muse, mutect2, varscan2
- NBAS | c.6905A>G p.K2302R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99868308; called by muse, mutect2, varscan2
- NBPF26 | c.1960C>T p.R654C (on ENST00000620612; = p.R392C on NM_001351372.1) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.835); catalogued as rs1553271556; called by muse, mutect2, varscan2
- NCAM1 | c.2299del p.A767Pfs*49 (on ENST00000316851 / NM_181351.5; = p.A757Pfs*49 on NM_000615.7) | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | catalogued as COSV57517570; called by mutect2, pindel, varscan2
- NCKAP1 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 47/242 reads (19%) | catalogued as COSV62940782; called by muse, varscan2
- NCOR1 | c.7085A>G p.Y2362C | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.819); catalogued as rs1481825972; called by muse, mutect2
- NDNF | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs372865079, COSV101113188, COSV65632616; called by muse, mutect2, varscan2
- NIN | c.4979C>T p.A1660V (on ENST00000382041 / NM_182946.1; = p.A947V on NM_016350.4) | Missense Mutation (SNP) | VAF 59/654 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs201587373, COSV55395750; called by muse, mutect2
- NLRP13 | c.3088A>G p.K1030E | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.03); catalogued as COSV61624454; called by muse, varscan2
- NOL6 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753538678, COSV53041015; called by mutect2, varscan2
- NOM1 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs141585452; called by muse, mutect2, varscan2
- NPAT | c.451_453del p.P151del | In Frame Del (DEL) | VAF 60/382 reads (16%) | catalogued as rs1293411143; called by pindel, varscan2
- NRDC | c.3472T>C p.Y1158H | Missense Mutation (SNP) | VAF 48/359 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); catalogued as rs761450381, COSV100543153; called by muse, mutect2, varscan2
- NRG1 | c.272del p.K91Sfs*24 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs1167519601; called by mutect2, pindel, varscan2
- NSFL1C | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | catalogued as COSV53794235; called by muse, mutect2
- NUP133 | c.1700A>C p.D567A | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV54569490, COSV99772761; called by muse, mutect2, varscan2
- NUP210L | c.3595A>C p.T1199P | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99667593; called by muse, mutect2
- ODF2L | c.11C>A p.A4D | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as COSV99643960; called by muse, mutect2
- OGDH | c.2921G>A p.R974Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1317570502; called by muse, mutect2, varscan2
- OGFOD3 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs368625223; called by muse, mutect2, varscan2
- OMA1 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs181552885, COSV100678014; called by muse, mutect2, varscan2
- OR2G3 | c.156T>G p.D52E | Missense Mutation (SNP) | VAF 253/1577 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV60682680; called by muse, mutect2, varscan2
- OR2K2 | c.539C>T p.T180M (on ENST00000374428; = p.T151M on NM_205859.2) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs746812189, COSV100235136; called by muse, mutect2, varscan2
- OR4A16 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100125091; called by muse, mutect2, varscan2
- OR5H1 | c.921del p.K307Nfs*? | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs750155763; called by mutect2, pindel
- OR5R1 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1458983231, COSV56571530; called by muse, mutect2, varscan2
- OR9G1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs758841935; called by muse, mutect2
- OTOGL | c.6501dup p.C2168Mfs*2 (on ENST00000547103; = p.C2159Mfs*2 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 76/208 reads (37%) | catalogued as rs1361238129; called by mutect2, varscan2
- OTUD6A | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100610879; called by muse, varscan2
- OXNAD1 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 57/320 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs369133759, COSV53267740; called by muse, mutect2, varscan2
- PABPC4 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100790859; called by muse, mutect2, varscan2
- PABPC5 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV57039174; called by muse, mutect2, varscan2
- PATL1 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.766); catalogued as rs769589438, COSV55691685; called by muse, mutect2, varscan2
- PAX3 | c.879del p.F294Sfs*87 | Frame Shift Del (DEL) | VAF 64/286 reads (22%) | catalogued as CD102010; called by mutect2, pindel, varscan2
- PAX6 | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV53792737; called by muse, mutect2, varscan2
- PCDHA3 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV100793489; called by muse, mutect2, varscan2
- PCDHGA2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); catalogued as rs868424998; called by muse, mutect2, varscan2
- PDE4A | c.1591C>T p.Q531* (on ENST00000380702 / NM_001111307.2; = p.Q292* on NM_006202.3) | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV53350958; called by muse, mutect2, varscan2
- PDE8A | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 137/2669 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs192339320, COSV100052352; called by muse, mutect2
- PDK2 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs752026536; called by muse, mutect2, varscan2
- PDZD2 | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs755711661, COSV56856241; called by mutect2, varscan2
- PFAS | c.2915G>A p.G972D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); catalogued as rs1243523189; called by muse, mutect2, varscan2
- PFKFB1 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 63/430 reads (15%) | PolyPhen possibly damaging (0.514); catalogued as rs934661751, COSV51499555, COSV99436674; called by muse, mutect2, varscan2
- PHACTR1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.048); catalogued as COSV60666355; called by muse, mutect2, varscan2
- PHC1 | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764756312; called by mutect2, varscan2
- PHKA1 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 37/289 reads (13%) | catalogued as rs781989524; called by muse, mutect2, varscan2
- PHOX2B | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1289168625; called by muse, mutect2, varscan2
- PHTF1 | c.1637del p.F546Sfs*2 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | catalogued as rs750248180; called by mutect2, varscan2
- PIGO | c.178del p.A60Pfs*15 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs1378962389; called by mutect2, pindel, varscan2
- PLXNA2 | c.2911A>G p.M971V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100885272; called by muse, mutect2, varscan2
- PLXNA2 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs772097656, COSV65440994; called by muse, mutect2, varscan2
- PNO1 | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV99718234; called by muse, mutect2
- POC5 | c.1273G>A p.G425R (on ENST00000428202 / NM_001099271.2; = p.G400R on NM_152408.2) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.744); catalogued as rs1431220354, COSV66842632; called by muse, mutect2
- POLR3A | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as rs185508362, COSV64930953; called by muse, mutect2, varscan2
- PPARGC1B | c.2863G>A p.A955T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV58531578; called by muse, mutect2, varscan2
- PPIA | c.332A>G p.Q111R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV99054538; called by muse, mutect2
- PPIL4 | c.991T>C p.Y331H | Missense Mutation (SNP) | VAF 103/1019 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.973); catalogued as COSV99481676; called by muse, mutect2, varscan2
- PPL | c.3920_3922del p.E1307del | In Frame Del (DEL) | VAF 61/400 reads (15%) | catalogued as rs1567983775; called by pindel, varscan2
- PPP1CA | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1465379397, COSV56704424; called by muse, mutect2, varscan2
- PPP1R9B | c.2221C>A p.L741M | Missense Mutation (SNP) | VAF 67/392 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57542101; called by muse, mutect2, varscan2
- PPP2R3A | c.695G>A p.C232Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1223181199; called by muse, mutect2, varscan2
- PPP3CC | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 62/364 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs142268010; called by muse, mutect2, varscan2
- PPP5C | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370743592; called by mutect2, varscan2
- PRDM7 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV57987772; called by muse, mutect2, varscan2
- PRH1 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.542); catalogued as rs758146734, COSV70372179; called by muse, mutect2, varscan2
- PRICKLE2 | c.2206C>T p.R736C (on ENST00000295902; = p.R680C on NM_198859.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as rs779550133; called by muse, varscan2
- PRKCB | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57772701; called by muse, mutect2, varscan2
- PRMT6 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV100791160; called by mutect2, varscan2
- PROKR1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs780773340, COSV58136990; called by muse, mutect2, varscan2
- PRR23B | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs780923964, COSV61494016; called by mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 31/104 reads (30%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSD4 | c.2422A>G p.T808A | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.055); catalogued as COSV99830956; called by muse, varscan2
- PSTK | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs747980417, COSV100924778; called by muse, mutect2, varscan2
- PTPN3 | c.1970dup p.P658Afs*20 | Frame Shift Ins (INS) | VAF 28/233 reads (12%) | catalogued as rs1564381860; called by mutect2, pindel, varscan2
- PTPN4 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs748499258, COSV99749906; called by muse, mutect2, varscan2
- RADIL | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs906532598, COSV68201903; called by muse, mutect2
- RAPSN | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs201197735, COSV54083931; called by muse, mutect2, varscan2
- RASGRP4 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1485409944; called by muse, mutect2, varscan2
- RBM26 | c.664C>A p.L222M | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs1444423306; called by muse, mutect2
- RBM28 | c.2160del p.A721Lfs*69 | Frame Shift Del (DEL) | VAF 118/1074 reads (11%) | catalogued as rs1205970712; called by mutect2, pindel, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | catalogued as COSV56484832; called by mutect2, varscan2
- RCAN2 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 75/377 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1232496824; called by muse, mutect2, varscan2
- RHOU | c.395G>A p.S132N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs780664653, COSV100797145; called by muse, mutect2, varscan2
- RNF145 | c.1376G>A p.R459H (on ENST00000424310 / NM_001199383.2; = p.R487H on NM_144726.2) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as rs778833400; called by muse, mutect2, varscan2
- RNF145 | c.1141C>T p.R381C (on ENST00000424310 / NM_001199383.2; = p.R409C on NM_144726.2) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246639416, COSV50868488; called by muse, mutect2, varscan2
- RNF220 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100131935; called by muse, mutect2, varscan2
- RNF43 | c.1954C>A p.P652T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1212768938; called by muse, varscan2
- RO60 | c.957A>G p.I319M | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV100814344; called by muse, mutect2, varscan2
- ROBO2 | c.3599C>T p.P1200L | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs376068100, COSV59925300; called by muse, mutect2, varscan2
- ROS1 | c.2495del p.K832Rfs*2 | Frame Shift Del (DEL) | VAF 23/113 reads (20%) | catalogued as rs36029166; called by mutect2, pindel, varscan2
- RPRM | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753673954, COSV100371538; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.947); catalogued as rs1212145377, COSV58242245; called by muse, mutect2, varscan2
- RPS6KA1 | c.989A>G p.Y330C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as rs1346636122, COSV100837909; called by muse, mutect2
- RPS6KA3 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.793); catalogued as COSV65387285; called by muse, mutect2, varscan2
- RPS6KA5 | c.874C>A p.R292S | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.556); catalogued as COSV56223160; called by muse, mutect2, varscan2
- RPUSD4 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as rs1406289497; called by muse, varscan2
- RRP1B | c.1934T>C p.F645S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs761507548; called by muse, mutect2, varscan2
- RSF1 | c.3250C>T p.R1084* | Nonsense Mutation (SNP) | VAF 75/393 reads (19%) | catalogued as COSV57840318; called by muse, mutect2, varscan2
- RTCB | c.736dup p.M246Nfs*6 | Frame Shift Ins (INS) | VAF 32/190 reads (17%) | catalogued as rs771992011; called by mutect2, varscan2
- RUSC1 | c.2647C>T p.R883C (on ENST00000368352 / NM_001105203.2; = p.R414C on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 142/634 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs376381554; called by mutect2, varscan2
- RYR2 | c.3974C>T p.A1325V | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100769031, COSV63692287; called by muse, mutect2
- RYR3 | c.10046G>A p.R3349Q (on ENST00000389232; = p.R3350Q on NM_001036.6) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as rs370501059; called by muse, mutect2, varscan2
- S100A7L2 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs563460549; called by muse, mutect2, varscan2
- SAFB | c.291_293del p.E98del | In Frame Del (DEL) | VAF 54/158 reads (34%) | catalogued as rs772452875; called by pindel, varscan2
- SARDH | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.195); catalogued as rs747222780; called by muse, mutect2, varscan2
- SCAI | c.1573+2T>C p.X525_splice (on ENST00000336505 / NM_001144877.3; = p.X548_splice on NM_173690.5) | Splice Site (SNP) | VAF 29/242 reads (12%) | catalogued as COSV57176186; called by muse, mutect2, varscan2
- SCAMP3 | c.65A>G p.Q22R | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100226637; called by muse, mutect2, varscan2
- SCEL | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs200625008, COSV62994688; called by mutect2, varscan2
- SCN3A | c.3723A>C p.E1241D | Missense Mutation (SNP) | VAF 100/550 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.51); catalogued as COSV99326281; called by muse, mutect2, varscan2
- SEC31B | c.1584G>C p.Q528H | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs1454735765; called by muse, mutect2, varscan2
- SEMA4A | c.1142T>C p.V381A | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV100740512; called by muse, mutect2, varscan2
- SESN1 | c.332C>T p.P111L (on ENST00000356644 / NM_001199933.1; = p.P170L on NM_014454.3) | Missense Mutation (SNP) | VAF 25/348 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271196492; called by muse, mutect2
- SH2D3A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as rs765407222, COSV55587002; called by muse, mutect2
- SH3BGRL | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV64620380; called by muse, mutect2, varscan2
- SHPRH | c.4435C>T p.R1479C (on ENST00000275233 / NM_001042683.3; = p.R1483C on NM_173082.3) | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759752193; called by muse, mutect2, varscan2
- SHROOM3 | c.2404G>A p.G802S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs769127601; called by mutect2, varscan2
- SINHCAF | c.218del p.N73Tfs*6 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs771414532; called by mutect2, varscan2
- SLC14A2 | c.2489C>T p.T830M | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs184792239, COSV54910828, COSV54912538; called by muse, mutect2, varscan2
- SLC19A3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367620430; called by muse, mutect2, varscan2
- SLC24A2 | c.538A>G p.M180V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99646883; called by muse, mutect2
- SLC24A4 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 50/333 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54119383; called by muse, mutect2, varscan2
- SLC26A4 | c.305-1G>T p.X102_splice | Splice Site (SNP) | VAF 31/683 reads (5%) | catalogued as rs1243584839; called by muse, mutect2
- SLC35B1 | c.937C>T p.R313* (on ENST00000649906; = p.R276* on NM_005827.4) | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as COSV53602459; called by muse, mutect2, varscan2
- SLC38A3 | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs866210794; called by muse, mutect2
- SLC43A1 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 55/501 reads (11%) | catalogued as rs202180094; called by muse, mutect2, varscan2
- SLC4A3 | c.2652del p.S885Afs*22 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as rs760972612; called by mutect2, pindel, varscan2
- SLC9A1 | c.2342C>T p.A781V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs556347900, COSV56051913; called by muse, mutect2, varscan2
- SLCO1B3 | c.1636_1637del p.L546Vfs*20 | Frame Shift Del (DEL) | VAF 47/256 reads (18%) | catalogued as rs78627909; called by mutect2, pindel, varscan2
- SLCO4C1 | c.1342A>G p.M448V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV60520461; called by muse, mutect2
- SLIT1 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs778164988; called by mutect2, varscan2
- SLX4 | c.4685C>T p.P1562L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1423103812; called by mutect2, varscan2
- SMAD5 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72505674; called by muse, mutect2
- SMURF1 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 52/378 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs774321941; called by muse, mutect2, varscan2
- SNAPC4 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs747793418; called by muse, mutect2, varscan2
- SNTB1 | c.1589A>G p.K530R | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67325791; called by muse, mutect2, varscan2
- SNX12 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV104370479, COSV52146479; called by muse, mutect2, varscan2
- SOGA1 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1313458212, COSV52928874; called by muse, mutect2, varscan2
- SOST | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200581535; called by muse, mutect2, varscan2
- SPATA18 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 80/422 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs59498549, COSV54648499; called by muse, varscan2
- SPATA32 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs781720235, COSV59305911; called by muse, mutect2
- SPATA6L | c.755C>T p.P252L (on ENST00000461761 / NM_001353484.2; = p.P194L on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/414 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as rs374967508; called by muse, mutect2, varscan2
- SPATS1 | c.901T>C p.*301Rext*2 | Nonstop Mutation (SNP) | VAF 116/540 reads (21%) | catalogued as rs988452292; called by muse, mutect2, varscan2
- SPRTN | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99149606; called by muse, mutect2, varscan2
- STAC | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs769980894, COSV56213071; called by muse, mutect2, varscan2
- SUPT3H | c.650G>A p.C217Y (on ENST00000371460 / NM_181356.3; = p.C206Y on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV60945305; called by muse, mutect2, varscan2
- SV2A | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.634); catalogued as rs781957523, COSV100975075; called by muse, mutect2, varscan2
- SYDE2 | c.869G>T p.W290L | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99320320; called by muse, mutect2, varscan2
- SYMPK | c.2771G>A p.R924H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99841783; called by muse, mutect2, varscan2
- SYN1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1197604545; called by muse, mutect2, varscan2
- SYNGAP1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53387128; called by muse, mutect2, varscan2
- SYNJ2 | c.3695del p.P1232Hfs*12 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs771695279, COSV62900492; called by pindel, varscan2
- SYT14 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.187); catalogued as COSV99654900; called by muse, mutect2
- SYTL4 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1203029035, COSV52167064, COSV99342908; called by muse, mutect2, varscan2
- TACC2 | c.8062C>T p.R2688W (on ENST00000334433; = p.R766W on NM_006997.4) | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs567347253; called by muse, mutect2, varscan2
- TAF1D | c.281del p.K94Rfs*26 | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | catalogued as rs746556335; called by mutect2, varscan2
- TAF1L | c.485del p.P162Rfs*4 | Frame Shift Del (DEL) | VAF 62/342 reads (18%) | catalogued as rs1564012601, COSV99645531; called by mutect2, pindel, varscan2
- TAGAP | c.1927G>A p.V643I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs372170128; called by muse, mutect2, varscan2
- TBC1D25 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.903); catalogued as COSV100952142; called by muse, mutect2, varscan2
- TCEA1 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1288459076; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs763321097; called by mutect2, varscan2
- TET1 | c.5234C>T p.T1745M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs144991411, COSV65386525; called by muse, mutect2, varscan2
- TLN2 | c.4315A>G p.T1439A | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.983); catalogued as rs769363908; called by muse, mutect2
- TM7SF3 | c.1325C>A p.S442* | Nonsense Mutation (SNP) | VAF 64/282 reads (23%) | catalogued as COSV58003532; called by muse, mutect2, varscan2
- TMEM132D | c.2609G>A p.S870N | Missense Mutation (SNP) | VAF 34/546 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1003069593; called by muse, mutect2
- TMEM87B | c.1540T>C p.W514R | Missense Mutation (SNP) | VAF 171/899 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99314177; called by muse, mutect2, varscan2
- TOGARAM2 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV101090985; called by muse, mutect2, varscan2
- TOGARAM2 | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV101090987; called by muse, mutect2, varscan2
- TOP2B | c.4321del p.S1441Vfs*41 (on ENST00000264331 / NM_001330700.2; = p.S1436Vfs*41 on NM_001068.3) | Frame Shift Del (DEL) | VAF 21/158 reads (13%) | catalogued as rs1293862281; called by mutect2, pindel, varscan2
- TRIM13 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs779143721, COSV53951911; called by muse, mutect2, varscan2
- TRIM42 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs1432924023, COSV53880010, COSV53884987; called by muse, mutect2, varscan2
- TRIOBP | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs377358503; called by muse, mutect2, varscan2
- TRPC4 | c.2152G>A p.V718I (on ENST00000379705 / NM_016179.4; = p.V723I on NM_003306.3) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.251); catalogued as rs377547600, COSV100158352; called by muse, mutect2, varscan2
- TRPM3 | c.2917G>A p.G973R (on ENST00000357533 / NM_001366142.2; = p.G816R on NM_020952.6) | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62593727; called by muse, mutect2, varscan2
- TRPM4 | c.734dup p.E246Rfs*25 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | catalogued as rs1254713847; called by pindel, varscan2
- TSC1 | c.2420T>G p.I807S | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as CM090945; called by muse, mutect2, varscan2
- TSC1 | c.737G>T p.R246M | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CS090916, CS090917, COSV53770736; called by muse, mutect2, varscan2
- TSPAN18 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs201625013; called by mutect2, varscan2
- TTC26 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 156/1161 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as rs753813712; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTI1 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65064217; called by muse, mutect2, varscan2
- TTN | c.50428C>T p.R16810* (on ENST00000591111; = p.R9386* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/76 reads (24%) | catalogued as rs1440093502, COSV60105753; called by muse, mutect2, varscan2
- TTN | c.14164C>T p.L4722F (on ENST00000591111; = p.L3795F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/327 reads (23%) | PolyPhen probably damaging (0.999); catalogued as rs917573806; called by muse, mutect2, varscan2
- TTN | c.5048G>A p.R1683Q (on ENST00000591111; = p.R1637Q on NM_003319.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | PolyPhen probably damaging (0.996); catalogued as rs368122582, COSV60323828; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 16/79 reads (20%) | PolyPhen benign (0.006); catalogued as rs368121196, COSV100605102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBGCP3 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV56186998; called by muse, mutect2
- TUBGCP5 | c.2136del p.D713Ifs*5 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | catalogued as rs1432092958; called by mutect2, pindel, varscan2
- TXLNA | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101009812, COSV101009813; called by muse, mutect2, varscan2
- TXLNB | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs754390761; called by muse, mutect2
- TYK2 | c.3193G>T p.V1065L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV99073956; called by mutect2, varscan2
- TYW5 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 48/626 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760126102, COSV63562501; called by muse, mutect2
- UBA7 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs769351638; called by muse, varscan2
- UBR4 | c.194A>G p.H65R | Missense Mutation (SNP) | VAF 56/335 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as COSV100920640; called by muse, mutect2, varscan2
- UNC5C | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV71662744; called by muse, mutect2
- USB1 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs146419360; called by muse, mutect2, varscan2
- USP2 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.813); catalogued as rs373153803; called by muse, mutect2, varscan2
- USP26 | c.1091T>A p.L364H | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV63707951; called by muse, mutect2, varscan2
- USP48 | c.2342T>G p.L781R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100379649; called by muse, mutect2, varscan2
- USP6NL | c.2423del p.P808Rfs*24 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as COSV53212543; called by mutect2, pindel, varscan2
- VIRMA | c.1520T>C p.L507S | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52591961; called by muse, mutect2
- VPS11 | c.511C>T p.Q171* (on ENST00000620429; = p.Q715* on NM_021729.6 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as rs1349785765; called by muse, mutect2, varscan2
- VPS13C | c.793A>G p.M265V (on ENST00000644861 / NM_020821.3; = p.M222V on NM_017684.5) | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1460744374; called by muse, mutect2
- VPS13D | c.12274G>A p.G4092R | Missense Mutation (SNP) | VAF 58/477 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99165918; called by muse, mutect2, varscan2
- WDFY3 | c.4993A>G p.T1665A | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1413336821; called by muse, mutect2, varscan2
- WDR3 | c.2807A>G p.E936G | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100308530; called by muse, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- WWC1 | c.2939G>A p.R980H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs758987247, COSV54650746; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs779864368; called by mutect2, pindel
- YARS1 | c.335T>C p.L112S | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100993331; called by muse, mutect2
- YIPF6 | c.593-1G>A p.X198_splice | Splice Site (SNP) | VAF 81/859 reads (9%) | catalogued as COSV101006188; called by muse, mutect2, varscan2
- ZBTB40 | c.2995A>G p.T999A | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100988867, COSV65146672; called by muse, mutect2, varscan2
- ZCCHC8 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 73/314 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs781567724; called by muse, varscan2
- ZDHHC6 | c.1225del p.E409Rfs*9 | Frame Shift Del (DEL) | VAF 15/139 reads (11%) | catalogued as COSV61129946; called by mutect2, pindel, varscan2
- ZMYM1 | c.2142G>T p.Q714H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100720930; called by muse, mutect2, varscan2
- ZMYM3 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 60/344 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58739270; called by muse, mutect2, varscan2
- ZNF107 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1259450801; called by muse, mutect2, varscan2
- ZNF160 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61999049; called by muse, mutect2, varscan2
- ZNF22 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs761209244; called by muse, mutect2, varscan2
- ZNF318 | c.1709T>C p.L570P | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs1562133916; called by muse, mutect2, varscan2
- ZNF319 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1567413437; called by muse, mutect2, varscan2
- ZNF345 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs560905535; called by mutect2, varscan2
- ZNF76 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.764); catalogued as rs757088149; called by muse, mutect2, varscan2
- ZW10 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs879576381; called by muse, mutect2, varscan2
- ABCB11 | c.3210del p.K1070Nfs*27 | Frame Shift Del (DEL) | VAF 29/186 reads (16%) | called by mutect2, pindel, varscan2
- ABCB7 | c.1577A>G p.K526R (on ENST00000373394 / NM_001271696.3; = p.K527R on NM_004299.6) | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCC8 | c.3262A>G p.T1088A | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ABCF3 | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- ACE2 | c.2269A>G p.I757V | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACKR4 | c.652del p.V218Cfs*11 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- ACSS3 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 61/271 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM32 | c.209del p.L70* | Frame Shift Del (DEL) | VAF 35/288 reads (12%) | called by mutect2, pindel, varscan2
- ADCY2 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 112/693 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- ADCY2 | c.3139A>G p.S1047G | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2
- ADGRV1 | c.2086G>A p.G696S | Missense Mutation (SNP) | VAF 49/324 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADH1A | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- AFAP1L2 | c.2050G>T p.G684W | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- AFF4 | c.3374C>G p.A1125G | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- AK5 | c.1197del p.K399Nfs*26 (on ENST00000354567 / NM_174858.3; = p.K373Nfs*26 on NM_012093.4) | Frame Shift Del (DEL) | VAF 35/284 reads (12%) | called by mutect2, pindel, varscan2
- AKNAD1 | c.942del p.K314Nfs*22 | Frame Shift Del (DEL) | VAF 48/272 reads (18%) | called by mutect2, pindel, varscan2
- ALB | c.1368del p.V457Wfs*25 | Frame Shift Del (DEL) | VAF 30/162 reads (19%) | called by mutect2, pindel, varscan2
- AMER2 | c.1862G>A p.S621N | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); called by muse, varscan2
- ANAPC5 | c.1630G>A p.V544I | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANKLE2 | c.1223A>G p.D408G | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD11 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- ANO7 | c.409C>T p.H137Y (on ENST00000274979; = p.H82Y on NM_001001666.4) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- AQR | c.4185G>T p.E1395D | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- ARAP1 | c.2188A>G p.M730V (on ENST00000393609 / NM_001040118.2; = p.M485V on NM_015242.4) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGEF2 | c.1855G>T p.E619* | Nonsense Mutation (SNP) | VAF 27/115 reads (23%) | called by muse, mutect2, varscan2
- ARHGAP1 | c.709del p.L237Cfs*135 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.1386A>T p.R462S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF12 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ATG101 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- BAZ2B | c.6479del p.K2160Sfs*8 | Frame Shift Del (DEL) | VAF 35/221 reads (16%) | called by mutect2, pindel, varscan2
- BCAM | c.1469dup p.S491Qfs*33 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by pindel, varscan2
- BCL6 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- BCL9L | c.4064del p.P1355Lfs*6 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- BDP1 | c.1790del p.N597Ifs*16 | Frame Shift Del (DEL) | VAF 49/273 reads (18%) | called by mutect2, pindel, varscan2
- BICRA | c.3575A>C p.Q1192P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BMPR1A | c.128dup p.S44Vfs*27 | Frame Shift Ins (INS) | VAF 24/134 reads (18%) | called by mutect2, pindel, varscan2
- BMPR2 | c.158A>G p.H53R | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- BNC2 | c.2588G>A p.C863Y | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BRAF | c.1577_1591del p.N526_P530del (on ENST00000288602 / NM_001374244.1; = p.N486_P490del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 24/292 reads (8%) | called by mutect2, pindel
- BTN3A3 | c.520del p.Q174Nfs*4 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | called by mutect2, pindel, varscan2
- C12orf40 | c.557del p.K186Sfs*19 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- C18orf32 | c.165G>A p.K55= | Splice Region (SNP) | VAF 69/419 reads (16%) | called by muse, mutect2, varscan2
- C1R | c.302G>T p.R101M (on ENST00000536053 / NM_001354346.2; = p.R87M on NM_001733.7) | Missense Mutation (SNP) | VAF 50/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- C21orf58 | c.540del p.T181Rfs*41 | Frame Shift Del (DEL) | VAF 14/18 reads (78%) | called by mutect2, varscan2
- C3orf22 | c.47G>T p.R16M | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- C3orf62 | c.427T>C p.W143R | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- C4orf46 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- C5 | c.4270A>G p.M1424V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- C7orf33 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- C9orf152 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 151/868 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CADPS2 | c.3853A>G p.I1285V | Missense Mutation (SNP) | VAF 96/356 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMK2B | c.1099A>G p.S367G | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.622); called by muse, mutect2
- CAMKK2 | c.1371G>T p.E457D | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CAND1 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 17/399 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.376); called by muse, mutect2
- CARD11 | c.701A>C p.H234P | Missense Mutation (SNP) | VAF 27/296 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.658); called by muse, mutect2
- CBLN2 | c.420dup p.G141Rfs*4 | Frame Shift Ins (INS) | VAF 38/382 reads (10%) | called by mutect2, pindel
- CCDC173 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 39/234 reads (17%) | called by muse, mutect2, varscan2
- CCDC178 | c.1596T>C p.G532= | Splice Region (SNP) | VAF 31/238 reads (13%) | called by muse, mutect2, varscan2
- CCNG2 | c.210del p.F70Lfs*22 | Frame Shift Del (DEL) | VAF 196/1087 reads (18%) | called by mutect2, pindel, varscan2
- CCNK | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- CDC123 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CDH20 | c.1823C>A p.P608Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDK19 | c.830C>A p.P277H | Missense Mutation (SNP) | VAF 29/652 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, mutect2
- CDON | c.3206T>G p.L1069R | Missense Mutation (SNP) | VAF 45/386 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- CDYL | c.1111-2A>G p.X371_splice (on ENST00000328908 / NM_001368125.1; = p.X317_splice on NM_004824.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- CELF2 | c.551T>C p.M184T (on ENST00000416382 / NM_001025077.3; = p.M191T on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CENPU | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 89/451 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CEP170 | c.1442del p.N481Ifs*26 | Frame Shift Del (DEL) | VAF 19/148 reads (13%) | called by mutect2, pindel, varscan2
- CEP57L1 | c.181del p.T61Lfs*9 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- CERS4 | c.190del p.L64* | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- CFAP206 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 73/319 reads (23%) | called by muse, mutect2, varscan2
- CFAP61 | c.1687C>A p.L563I | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP65 | c.2422C>A p.L808M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.138); called by mutect2, varscan2
- CGNL1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CHD9 | c.5393del p.N1798Tfs*17 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- CHRNA6 | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST15 | c.231dup p.K78Efs*4 | Frame Shift Ins (INS) | VAF 24/135 reads (18%) | called by mutect2, pindel, varscan2
- CHSY3 | c.713del p.K238Sfs*4 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- CIITA | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CIP2A | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLMN | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 43/320 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNOT1 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 88/664 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, varscan2
- COG1 | c.2570del p.F857Sfs*23 | Frame Shift Del (DEL) | VAF 39/128 reads (30%) | called by mutect2, pindel, varscan2
- COG7 | c.1760T>C p.F587S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- COL28A1 | c.1306del p.D436Ifs*2 | Frame Shift Del (DEL) | VAF 33/152 reads (22%) | called by mutect2, pindel, varscan2
- COL4A5 | c.1814C>A p.P605H | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- COL7A1 | c.5261del p.P1754Qfs*87 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- COLQ | c.394-1G>T p.X132_splice | Splice Site (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2
- COX15 | c.362T>C p.F121S | Missense Mutation (SNP) | VAF 65/331 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPNE5 | c.624G>T p.E208D | Missense Mutation (SNP) | VAF 56/299 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- CRBN | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CSF3 | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CSMD3 | c.4234+2T>C p.X1412_splice (on ENST00000297405 / NM_001363185.1; = p.X1308_splice on NM_052900.3) | Splice Site (SNP) | VAF 31/184 reads (17%) | called by muse, mutect2, varscan2
- CSRNP1 | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by mutect2, varscan2
- CYP11B2 | c.228del p.I78Ffs*14 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- CYTH2 | c.167+2T>C p.X56_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- DAAM2 | c.1144C>A p.H382N | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- DCC | c.2113G>T p.G705* | Nonsense Mutation (SNP) | VAF 12/217 reads (6%) | called by muse, mutect2
- DCP1A | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DDX50 | c.271T>C p.S91P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- DDX55 | c.1534A>T p.R512* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- DENND3 | c.2239C>T p.L747F | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DENND5B | c.3759T>G p.I1253M | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- DENND6A | c.292T>G p.Y98D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DEPDC4 | c.641A>T p.N214I | Missense Mutation (SNP) | VAF 48/916 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2
- DICER1 | c.5654T>C p.V1885A | Missense Mutation (SNP) | VAF 32/640 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.967); called by muse, mutect2
- DIPK2B | c.226_228del p.E76del | In Frame Del (DEL) | VAF 20/101 reads (20%) | called by pindel, varscan2
- DNAH10 | c.1675del p.D559Tfs*15 (on ENST00000409039; = p.D498Tfs*15 on NM_207437.3) | Frame Shift Del (DEL) | VAF 59/391 reads (15%) | called by mutect2, pindel, varscan2
- DNAH11 | c.10691A>G p.K3564R | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAH12 | c.787T>C p.W263R | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH3 | c.1445T>C p.F482S | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- DNAH5 | c.9105+1G>A p.X3035_splice | Splice Site (SNP) | VAF 68/358 reads (19%) | called by muse, mutect2, varscan2
- DNAJB13 | c.683A>T p.D228V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNM1L | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 113/385 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- DNMBP | c.4191del p.S1398Lfs*25 | Frame Shift Del (DEL) | VAF 22/156 reads (14%) | called by mutect2, pindel, varscan2
- DNMBP | c.2054T>G p.L685R | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- DOCK1 | c.2807C>T p.T936I | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DOCK5 | c.751T>C p.S251P | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- DOCK9 | c.5210A>G p.Y1737C (on ENST00000376460 / NM_001366676.2; = p.Y1738C on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DOLK | c.1204G>T p.G402* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- DPH5 | c.406del p.W136Gfs*14 | Frame Shift Del (DEL) | VAF 66/430 reads (15%) | called by pindel, varscan2
- DZIP1L | c.1927del p.R643Gfs*40 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | called by mutect2, pindel, varscan2
- EEF2K | c.944A>T p.N315I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EFNB3 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- EGFLAM | c.1306del p.D436Ifs*26 | Frame Shift Del (DEL) | VAF 16/177 reads (9%) | called by mutect2, pindel
- EHF | c.602del p.K201Sfs*18 | Frame Shift Del (DEL) | VAF 25/147 reads (17%) | called by mutect2, pindel, varscan2
- EIF4ENIF1 | c.1556G>A p.G519D | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- EIF4H | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ELOVL2 | c.44del p.L15Wfs*42 | Frame Shift Del (DEL) | VAF 36/298 reads (12%) | called by pindel, varscan2
- EP300 | c.4408del p.M1470Cfs*26 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | called by mutect2, varscan2
- EPHA4 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 97/536 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB1 | c.2786G>T p.R929M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPS15L1 | c.1589_1591del p.I530del | In Frame Del (DEL) | VAF 14/114 reads (12%) | called by pindel, varscan2
- ERCC6L | c.2635C>A p.P879T | Missense Mutation (SNP) | VAF 88/584 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- EXOC1 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- EXOC1 | c.2469del p.G824Vfs*2 | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | called by mutect2, pindel, varscan2
- FAM122B | c.16del p.M6Wfs*15 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by pindel, varscan2
- FAM131B | c.444del p.E149Rfs*3 | Frame Shift Del (DEL) | VAF 16/117 reads (14%) | called by mutect2, pindel, varscan2
- FAM135A | c.2996dup p.N999Kfs*2 (on ENST00000370479 / NM_001351599.1; = p.N786Kfs*2 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 16/106 reads (15%) | called by mutect2, varscan2
- FAM13A | c.1092A>G p.E364= | Splice Region (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- FAM47A | c.2086G>T p.G696* | Nonsense Mutation (SNP) | VAF 71/433 reads (16%) | called by muse, mutect2, varscan2
- FBXO48 | c.440_*1delinsGAAATTCTAGAAGCAGAACTGGAAAGATAA | Missense Mutation (ONP) | VAF 58/509 reads (11%) | called by pindel, varscan2*
- FER | c.1428del p.K476Nfs*53 | Frame Shift Del (DEL) | VAF 61/342 reads (18%) | called by mutect2, varscan2
- FER1L6 | c.3966+1G>A p.X1322_splice | Splice Site (SNP) | VAF 53/344 reads (15%) | called by muse, mutect2, varscan2
- FGA | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.02); called by mutect2, varscan2
- FKBP14 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLNC | c.3337G>T p.G1113C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FMNL3 | c.2487G>T p.E829D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); called by muse, mutect2
- FRMD4A | c.1492A>C p.T498P | Missense Mutation (SNP) | VAF 90/640 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- FSTL4 | c.2499del p.T834Pfs*59 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel, varscan2
- FZD2 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA4 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- GABRB2 | c.177del p.V60Wfs*5 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- GALE | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GATA1 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- GEMIN5 | c.1730A>G p.H577R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GJA8 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- GNAL | c.998del p.L333* (on ENST00000269162 / NM_001142339.3; = p.L410* on NM_182978.4) | Frame Shift Del (DEL) | VAF 190/1302 reads (15%) | called by mutect2, pindel, varscan2
- GPAT3 | c.344G>T p.R115M | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GPATCH8 | c.4070A>G p.Q1357R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.383); called by mutect2, varscan2
- GPR143 | c.399G>A p.W133* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- GPR156 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR160 | c.715del p.I239Yfs*22 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- GPR31 | c.924G>T p.E308D | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- GPRASP1 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GPRASP2 | c.87_88dup p.N30Rfs*52 | Frame Shift Ins (INS) | VAF 9/69 reads (13%) | called by mutect2, varscan2
- GPRASP2 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by mutect2, varscan2
- GPRC6A | c.142del p.M48Cfs*30 | Frame Shift Del (DEL) | VAF 42/194 reads (22%) | called by mutect2, varscan2
- GRK5 | c.679G>T p.G227W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSK3A | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HCFC2 | c.1247C>A p.P416H | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.339); called by muse, mutect2
- HEATR3 | c.955del p.D319Mfs*3 | Frame Shift Del (DEL) | VAF 14/118 reads (12%) | called by mutect2, pindel, varscan2
- HECW2 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- HERC1 | c.10608G>T p.E3536D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- HIPK2 | c.1863G>T p.Q621H | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2
- HIRA | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HIRIP3 | c.301+2T>G p.X101_splice | Splice Site (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2
- HIVEP1 | c.7209del p.I2404Sfs*57 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.3578A>G p.Q1193R | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- HK1 | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, varscan2
- HNRNPD | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- HNRNPR | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 24/371 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- HPS3 | c.947A>G p.Q316R | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HUWE1 | c.6947G>T p.G2316V | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- HYDIN | c.5620-2A>G p.X1874_splice | Splice Site (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- ICA1 | c.218T>C p.L73S | Missense Mutation (SNP) | VAF 70/598 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFIT2 | c.200del p.N67Tfs*14 | Frame Shift Del (DEL) | VAF 35/157 reads (22%) | called by mutect2, pindel, varscan2
- IFNLR1 | c.447del p.C150Afs*7 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, varscan2
- IGDCC4 | c.1765A>G p.N589D | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- IGHV4-61 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- IKBIP | c.801A>C p.R267S | Missense Mutation (SNP) | VAF 14/399 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IL16 | c.1857_1858dup p.N620Rfs*67 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- IL2RB | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IMPDH2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- INMT | c.448G>C p.A150P | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- INTS2 | c.2433_2436del p.T812Sfs*11 | Frame Shift Del (DEL) | VAF 25/196 reads (13%) | called by mutect2, pindel, varscan2
- INTS6L | c.236dup p.N79Kfs*19 | Frame Shift Ins (INS) | VAF 27/198 reads (14%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.2333A>C p.N778T | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2
- IREB2 | c.2222A>G p.H741R | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2
- IRF2BPL | c.584del p.G195Afs*17 | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | called by mutect2, pindel, varscan2
- ITGA4 | c.1843dup p.T615Nfs*11 | Frame Shift Ins (INS) | VAF 18/98 reads (18%) | called by mutect2, varscan2
- ITGAV | c.2336G>A p.S779N | Missense Mutation (SNP) | VAF 48/271 reads (18%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- ITGB1BP1 | c.21del p.K7Nfs*59 | Frame Shift Del (DEL) | VAF 56/474 reads (12%) | called by pindel, varscan2
- KANK2 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- KBTBD6 | c.1940G>A p.G647D | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- KCNC2 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- KDM3B | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA1210 | c.1504A>G p.N502D | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, varscan2
- KIAA1217 | c.4353G>A p.M1451I | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIAA1549L | c.3757A>T p.T1253S (on ENST00000321505; = p.T1550S on NM_012194.3) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF16B | c.3712-1G>A p.X1238_splice | Splice Site (SNP) | VAF 53/348 reads (15%) | called by muse, mutect2, varscan2
- KIF1A | c.2685G>T p.E895D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF4A | c.2522T>C p.L841P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KIF5B | c.681_682del p.Y228Sfs*3 | Frame Shift Del (DEL) | VAF 51/485 reads (11%) | called by mutect2, pindel, varscan2
- KLC1 | c.1406del p.N469Tfs*18 | Frame Shift Del (DEL) | VAF 16/124 reads (13%) | called by mutect2, pindel, varscan2
- KLHDC3 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2
- KLHL3 | c.1247A>G p.Y416C | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- KLHL4 | c.193dup p.S65Kfs*31 | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- KMT2B | c.3908G>A p.C1303Y | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2B | c.7079C>A p.P2360Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); called by mutect2, varscan2
- KMT2C | c.8599_8600del p.K2867Dfs*7 | Frame Shift Del (DEL) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- KNTC1 | c.3736G>T p.G1246C | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2
- KRT71 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.117); called by muse, mutect2
- KRT75 | c.1592del p.G531Afs*52 | Frame Shift Del (DEL) | VAF 26/111 reads (23%) | called by mutect2, pindel, varscan2
- KRTAP10-9 | c.282del p.C95Afs*286 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel
- LACRT | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 65/445 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- LAG3 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 48/500 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, mutect2
- LAMA2 | c.8953del p.M2985Wfs*8 | Frame Shift Del (DEL) | VAF 42/346 reads (12%) | called by mutect2, pindel, varscan2
- LAMB4 | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCOR | c.383A>C p.D128A | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- LCT | c.2781del p.G928Afs*16 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- LEMD3 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- LETM1 | c.538C>A p.R180S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- LIAS | c.672del p.K224Nfs*8 (on ENST00000261434 / NM_001363700.2; = p.K327Nfs*8 on NM_006859.4) | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- LMTK2 | c.1412G>A p.G471D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP2BP | c.771del p.K257Nfs*24 | Frame Shift Del (DEL) | VAF 23/190 reads (12%) | called by mutect2, pindel, varscan2
- LRRCC1 | c.523A>G p.N175D | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRIQ1 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- LSM6 | c.7C>A p.L3I | Missense Mutation (SNP) | VAF 116/500 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LTBP2 | c.4504T>C p.C1502R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LZTFL1 | c.91del p.T31Lfs*2 | Frame Shift Del (DEL) | VAF 31/224 reads (14%) | called by mutect2, pindel, varscan2
- MAGEB2 | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- MAN2B2 | c.751A>C p.S251R | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- MAOB | c.1195A>T p.T399S | Missense Mutation (SNP) | VAF 81/613 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- MAP11 | c.1132T>C p.S378P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MAP3K13 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- MAP4K2 | c.891del p.S298Pfs*38 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- MAPK10 | c.281C>T p.P94L (on ENST00000359221 / NM_001351625.2; = p.P132L on NM_002753.5) | Missense Mutation (SNP) | VAF 95/561 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAPK6 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MARCHF5 | c.307G>T p.G103* | Nonsense Mutation (SNP) | VAF 134/639 reads (21%) | called by muse, mutect2, varscan2
- MATR3 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.351); called by muse, mutect2
- MCAT | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCM10 | c.1439A>G p.K480R (on ENST00000484800 / NM_182751.3; = p.K479R on NM_018518.5) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- MCM6 | c.1095del p.K365Nfs*6 | Frame Shift Del (DEL) | VAF 26/129 reads (20%) | called by mutect2, pindel, varscan2
- MDN1 | c.12229del p.L4077Cfs*15 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- ME1 | c.1688T>C p.V563A | Missense Mutation (SNP) | VAF 64/448 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ME2 | c.733A>G p.R245G | Missense Mutation (SNP) | VAF 125/679 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MED12 | c.1248+2T>C p.X416_splice | Splice Site (SNP) | VAF 75/425 reads (18%) | called by muse, mutect2, varscan2
581 further variants in this file (254 protein-altering or splice-affecting, 311 silent, 16 other) are not listed here.
